Surgical pathology report (de-identified scan), TCGA case TCGA-55-6978, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6978-01A (Primary Tumor).

[page 1 of 2]
Requested by:

Surgical Report - STATUS: Final
See Text
Ordered By:
Facility

Perform Date
Ordered Date
Department

Service Report Text

SEE REPORT

ADDENDUM INFORMATION

ACCESSION #:

PROCEDURE DATE:

==== ADDENDUM REPORT #1; COMMENT: =====

SPECIAL STAINS:

STAIN	RESULT
TTF-1	positive, patchy, nuclear pattern
p63	negative
CK5/6	negative
uroplakin	nonspecific background staining, negative
CK7	negative
CK20	negative

The immunoprofile supports a poorly differentiated neoplasm of pulmonary origin rather than metastatic urothelial carcinoma. The absence of CK5/6 and p63 expression favors this is most likely a very poorly differentiated adenocarcinoma.

These findings are supplementary only and do not change the previously reported diagnoses.

==== ADDENDUM REPORT #1; DIAGNOSIS: =====

SEE ORIGINAL DIAGNOSIS

SURGICAL PATHOLOGY REPORT

ACCESSION #:

PROCEDURE DATE:

==== SPECIMEN DESCRIPTION: =====

- A. INFERIOR PULMONARY LIGAMENT LYMPH NODE
- B. PERIESOPHAGEAL LYMPH NODE
- C. SUBCARINAL LYMPH NODE, CPC
- D. PARATRACHEAL LYMPH NODE
- E. PROXIMAL LYMPH NODE

[page 2 of 2]
Requested by:

F/FPC. MIDDLE AND LOWER LOBES, RIGHT LUNG, DOUBLE LOBECTOMY WITH
INTRAOPERATIVE PATHOLOGIC CONSULTATION:

1. TUMOR SITE: MIDDLE LOBE
2. MAXIMUM TUMOR SIZE (GROSS): 5.5 X 5.0 CM
3. TUMOR FOCALITY: UNIFOCA
4. HISTOLOGIC TYPE: NONSMALL CELL CARCINOMA; SEE DESCRIPTION,
IMMUNOEVALUATION IS PENDING
5. HISTOLOGIC GRADE: G3, POORLY DIFFERENTIATED
6. VISCERAL PLEURAL INVASION: NEGATIVE
7. TUMOR EXTENSION: TUMOR EXTENDS INTO FISSURE
8. BRONCHIAL MARGIN: NEGATIVE FOR TUMOR, 2.5 CM DISTANT, NO
SQUAMOUS CELL CARCINOMA IN SITU IDENTIFIED
9. VASCULAR PARENCHYMAL PARIETAL PLEURAL MARGINS: ALL NEGATIVE FOR
CARCINOMA
10. TREATMENT EFFECT: NOT APPLICABLE
11. TUMOR ASSOCIATED PNEUMONIA/FIBROSIS: PRESENT
12. LYMPH VASCULAR INVASION: INDETERMINATE BUT FAVOR PRESENT, BLOCK
4
13. LYMPH NODES: TWELVE LYMPH NODES, INCLUDING PARTS A THROUGH E,
BLOCK F1 (NEGATIVE FOR
14. PATHOLOGIC STAGE: pT2bN0M0

----- PATHOLOGIST COMMENT: -----

Characterization of tumor type is pending immunoevaluation; an addendum report
will be issued.

Source: NCI Genomic Data Commons file f24e4ff0-55b7-4d9d-af49-dcc9193c7c91 (TCGA-55-6978.3E3C1E82-EE09-4EEB-873A-9B6580274F97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).